Somatic mutation profile of tumor specimen ER-ADRU-TTP1-A (aliquot ER-ADRU-TTP1-A-1-0-D-A519-35) from EXCEPTIONAL_RESPONDERS case ER-ADRU, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,714 days).
Specimen ER-ADRU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a614c3f2-e7a9-42ac-be82-87e53c1ec3a0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADRU-NT1-A (Solid Tissue Normal), aliquot ER-ADRU-NT1-A-1-0-D-A519-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/992cd478-e9ae-4efb-9c15-06df864ea726

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 28/359 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic; called by muse, mutect2
- RBM10 | c.992T>A p.V331E | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RSPO2 | c.-169-170C>T | Intron (SNP) | VAF 17/462 reads (4%) | called by muse, mutect2
